Gene-level copy-number profile of tumor specimen MP2PRT-PARUYH-TMP1-A from MP2PRT case MP2PRT-PARUYH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,216 days).
Specimen MP2PRT-PARUYH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 96b77407-62c4-4799-b31f-bc84859995b8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARUYH-NM1-A (blood derived cancer - bone marrow, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/0a77b628-5cff-4a7a-b26e-5ca1f1cfe031

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 238; copy number 1: 118; copy number 2: 57,957; copy number 3: 74.

Homozygous deletions (total copy number 0; autosomes only): 238 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,245,596, 36 genes (within-gene range 0–2): IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr2:89,968,867–90,022,185, 7 genes: IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21.
- chr2:90,114,838–90,173,414, 5 genes: IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11.
- chr9:20,331,446–22,029,594, 58 genes (within-gene range 0–2): AL512635.1, MLLT3, MIR4473, RNU4-26P, MIR4474, AL163193.1, FOCAD, FOCAD-AS1, MIR491, SNORA30B, HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–21,996,013, 1 gene (within-gene range 0–2): AL449423.1.
- chr14:22,438,547–22,450,139, 4 genes (within-gene range 0–2): TRDD1, TRDD2, TRDD3, TRDJ1.
- chr14:105,672,308–106,538,344, 125 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,564,375–106,566,555, 2 genes (within-gene range 0–2): IGHVII-49-1, IGHV3-50.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 118. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
